Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EE, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EE-01A (Primary Tumor).

100-0-3
Melanoma, epithelioid cell
8721/3
Site @ Chocoma 069.3
JW 8/10/14

Macroscopy

Microscopy

Conclusion

The ciliary body, the iris and the anterior chamber as well as the optic nerve on its entire course (pre and post laminar, optic foramen, meningeal sheaths and cut end) are free.

Source: NCI Genomic Data Commons file adec443e-5abf-4b0a-84ac-85664750cd13 (TCGA-V4-A9EE.780F5B34-05FF-44A1-B9F4-062D737246FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).